CCDI case PBCSAC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e0944799-442f-4c63-b0ff-006244ededed

Demographics
Sex at birth: female.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (55 days).

Biospecimens (2 samples)
- Sample 0DY77T: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DY79H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
